Somatic mutation profile of tumor specimen TCGA-69-7978-01A (aliquot TCGA-69-7978-01A-11D-2184-08) from TCGA case TCGA-69-7978, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 59.6 years (21,785 days).
Specimen TCGA-69-7978-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b92a1403-9236-4afb-b55d-0de75270aba1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-69-7978-10A (Blood Derived Normal), aliquot TCGA-69-7978-10A-01D-2184-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4ea9860a-b1c6-435b-a9f1-964ac7e77793

The open-access MAF lists 625 somatic variants for this specimen: 455 protein-altering or splice-affecting, 157 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 394, Silent 157, Nonsense Mutation 40, Splice Site 9, Intron 7, Frame Shift Del 7, Splice Region 3, RNA 3, 3'UTR 1, Translation Start Site 1, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 9/30 reads (30%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AATK | c.2797C>G p.R933G (on ENST00000326724 / NM_001080395.3; = p.R830G on NM_004920.2) | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as COSV58370166; called by muse, mutect2
- ABCA13 | c.12428G>T p.G4143V | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101446844; called by muse, mutect2, varscan2
- ABCB1 | c.433C>A p.H145N | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as COSV99712336; called by muse, mutect2, varscan2
- ABCG8 | c.739A>C p.T247P | Missense Mutation (SNP) | VAF 23/169 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV55395103; called by muse, mutect2, varscan2
- ABHD2 | c.798G>C p.K266N | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.034); catalogued as COSV61775307; called by muse, mutect2, varscan2
- ACSM2A | c.927G>T p.M309I (on ENST00000219054; = p.M230I on NM_001308169.2) | Missense Mutation (SNP) | VAF 17/211 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV54586691, COSV54587441; called by muse, mutect2
- ACTN2 | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.975); catalogued as COSV63971817, COSV63976965; called by muse, mutect2, varscan2
- ADCY2 | c.1309G>A p.G437S | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); catalogued as rs142609557; called by muse, mutect2, varscan2
- ADGRB2 | c.3307A>G p.M1103V | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV57076426; called by muse, mutect2, varscan2
- ADGRE5 | c.191-1G>C p.X64_splice | Splice Site (SNP) | VAF 5/35 reads (14%) | catalogued as COSV54413141; called by muse, mutect2, varscan2
- ADGRG4 | c.1429G>T p.A477S | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.109); catalogued as COSV54962233; called by muse, mutect2, varscan2
- ADGRG4 | c.6320C>A p.A2107E | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.074); catalogued as COSV54962245; called by muse, mutect2, varscan2
- ADGRL2 | c.2027G>C p.S676T (on ENST00000370717 / NM_001366005.1; = p.S663T on NM_012302.4) | Missense Mutation (SNP) | VAF 48/178 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.263); catalogued as COSV54678245; called by muse, mutect2, varscan2
- AFF2 | c.3155C>T p.S1052F | Missense Mutation (SNP) | VAF 36/219 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV53998879; called by muse, mutect2, varscan2
- AGTR1 | c.657G>T p.W219C | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.91); catalogued as COSV62557497, COSV62559219; called by muse, mutect2, varscan2
- AKAP13 | c.1927C>G p.Q643E | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as rs199949454; called by muse, mutect2
- AKAP4 | c.170A>T p.Y57F | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV62074976; called by muse, mutect2, varscan2
- AKAP9 | c.706C>G p.Q236E | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV62352781; called by muse, mutect2
- AKR1B15 | c.263A>T p.Q88L | Missense Mutation (SNP) | VAF 49/240 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.741); catalogued as COSV71152473; called by muse, mutect2, varscan2
- ALG13 | c.2529G>T p.K843N | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV52642397; called by muse, mutect2, varscan2
- ALS2CL | c.1879G>T p.V627L | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.054); catalogued as rs138602401, COSV59672664; called by muse, mutect2, varscan2
- ANK2 | c.745G>C p.A249P | Missense Mutation (SNP) | VAF 11/151 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52175731, COSV52195154; called by muse, mutect2
- ANKRD28 | c.2425G>C p.D809H | Missense Mutation (SNP) | VAF 33/250 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as COSV67519377; called by muse, mutect2, varscan2
- APC | c.1252G>A p.E418K | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV57348738, COSV57363838, COSV57384634; called by muse, mutect2
- APH1A | c.91C>T p.R31C | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV52528642; called by muse, mutect2
- APMAP | c.754T>G p.L252V | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.39); catalogued as COSV54175589; called by muse, mutect2, varscan2
- APOBEC3C | c.436G>T p.E146* | Nonsense Mutation (SNP) | VAF 26/187 reads (14%) | catalogued as COSV53327542; called by muse, mutect2, varscan2
- AREL1 | c.1852A>G p.M618V | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1250467124, COSV62667280; called by muse, mutect2, varscan2
- ARHGAP35 | c.380C>G p.S127* | Nonsense Mutation (SNP) | VAF 3/36 reads (8%) | catalogued as COSV68333703; called by muse, mutect2
- ARHGAP35 | c.1261G>C p.E421Q | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT tolerated (0.8); PolyPhen benign (0.01); catalogued as rs1273600566, COSV68328901, COSV68333715; called by muse, mutect2, varscan2
- ARSG | c.695A>T p.Q232L | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.272); catalogued as COSV71593725; called by muse, mutect2, varscan2
- ATIC | c.183G>T p.L61F | Missense Mutation (SNP) | VAF 32/258 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52694437; called by muse, mutect2, varscan2
- ATN1 | c.3199G>C p.D1067H | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV57547261; called by muse, mutect2
- ATP2C1 | c.1598T>A p.L533Q | Missense Mutation (SNP) | VAF 12/141 reads (9%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.836); catalogued as COSV60759535; called by muse, mutect2
- ATP8B4 | c.2953G>T p.G985W | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52720195; called by muse, mutect2, varscan2
- B3GALNT2 | c.290A>G p.H97R | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV58356966; called by muse, mutect2
- BBS2 | c.1945G>A p.D649N | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV55327633; called by muse, mutect2
- BCL6 | c.1214C>T p.P405L | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51654182; called by muse, mutect2
- BIRC6 | c.10324C>G p.Q3442E | Missense Mutation (SNP) | VAF 14/205 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); catalogued as COSV70203237; called by muse, mutect2
- BMX | c.1456T>C p.Y486H | Missense Mutation (SNP) | VAF 21/166 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59592376, COSV59592426; called by muse, mutect2, varscan2
- BRINP3 | c.2015G>C p.S672T | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV66517557, COSV66532855; called by muse, mutect2
- BTBD6 | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.145); catalogued as COSV59271527; called by muse, mutect2, varscan2
- C4B | c.3347C>T p.S1116L | Missense Mutation (SNP) | VAF 15/146 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as rs767540386, COSV70313250; called by muse, mutect2, varscan2
- C9 | c.1066T>C p.Y356H | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54679269; called by muse, mutect2, varscan2
- C9orf24 | c.400G>T p.A134S | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.045); catalogued as COSV52624996; called by muse, mutect2, varscan2
- CA10 | c.218C>T p.T73I | Missense Mutation (SNP) | VAF 41/270 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.776); catalogued as COSV53361162; called by muse, mutect2, varscan2
- CABIN1 | c.157G>C p.E53Q | Missense Mutation (SNP) | VAF 7/141 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.089); catalogued as COSV54085843; called by muse, mutect2
- CACNA1C | c.4970C>A p.T1657K | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV100216280; called by muse, mutect2
- CALCR | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 12/97 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.051); catalogued as COSV100810431; called by muse, mutect2, varscan2
- CALML6 | c.399G>T p.K133N | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV57070042; called by muse, mutect2, varscan2
- CAMSAP2 | c.3621G>C p.K1207N (on ENST00000236925 / NM_001297707.2; = p.K1196N on NM_203459.3) | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as COSV52674245; called by muse, mutect2
- CAMTA1 | c.2353G>T p.G785W | Missense Mutation (SNP) | VAF 48/555 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV57915242; called by muse, mutect2
- CATSPERG | c.3435C>G p.D1145E | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.005); catalogued as COSV53051304; called by muse, mutect2, varscan2
- CCDC141 | c.2122G>T p.V708L | Missense Mutation (SNP) | VAF 32/174 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.086); catalogued as COSV55378200; called by muse, mutect2, varscan2
- CCDC149 | c.711G>C p.L237F | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60880551; called by muse, mutect2
- CCDC171 | c.1837G>T p.D613Y | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52647448; called by muse, mutect2, varscan2
- CCDC172 | c.384G>T p.L128F | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.063); catalogued as COSV60939232; called by muse, mutect2, varscan2
- CCDC184 | c.219G>T p.Q73H | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100343928; called by muse, mutect2, varscan2
- CD22 | c.1712G>A p.C571Y | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50059859; called by muse, mutect2
- CD300E | c.292G>T p.D98Y | Missense Mutation (SNP) | VAF 38/202 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60791164; called by muse, mutect2, varscan2
- CD96 | c.1376C>G p.S459* (on ENST00000283285 / NM_198196.3; = p.S443* on NM_005816.5) | Nonsense Mutation (SNP) | VAF 11/124 reads (9%) | catalogued as COSV51919615; called by muse, mutect2
- CDC20 | c.211C>G p.P71A | Missense Mutation (SNP) | VAF 6/148 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as COSV60522587; called by muse, mutect2
- CDK15 | c.282C>A p.S94R (on ENST00000652192 / NM_001366386.2; = p.S43R on NM_139158.2) | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV53636481; called by muse, mutect2, varscan2
- CELSR1 | c.4742C>G p.A1581G | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV53095079; called by muse, mutect2, varscan2
- CES5A | c.473A>C p.D158A | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV51868650; called by muse, mutect2, varscan2
- CETP | c.1444G>A p.E482K | Missense Mutation (SNP) | VAF 13/194 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs1222822718, COSV52363568; called by muse, mutect2
- CFAP65 | c.389C>A p.S130Y (on ENST00000341552 / NM_194302.4; = p.S65Y on NM_152389.4) | Missense Mutation (SNP) | VAF 22/199 reads (11%) | SIFT tolerated (0.61); PolyPhen benign (0.025); catalogued as COSV55391045; called by muse, mutect2, varscan2
- CHEK2 | c.1216C>T p.L406F (on ENST00000382580 / NM_001005735.2; = p.L363F on NM_007194.4) | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1569115748, COSV60423435; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHL1 | c.2516A>G p.H839R (on ENST00000397491 / NM_001253387.1; = p.H855R on NM_006614.4) | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs576424714, COSV56599239; called by muse, mutect2, varscan2
- CHMP7 | c.954T>A p.D318E | Missense Mutation (SNP) | VAF 34/378 reads (9%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.984); catalogued as COSV57533441; called by muse, mutect2
- CIT | c.430G>T p.E144* | Nonsense Mutation (SNP) | VAF 21/218 reads (10%) | catalogued as COSV55876490; called by muse, mutect2, varscan2
- CLEC14A | c.1361C>A p.S454Y | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV60563532; called by muse, mutect2
- CLMP | c.185T>A p.V62E | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs781743198, COSV71650330; called by muse, mutect2
- CLTC | c.344C>T p.S115F | Missense Mutation (SNP) | VAF 13/190 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs748270835, COSV52250167; called by muse, mutect2
- CNST | c.313G>T p.D105Y | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100829814; called by muse, mutect2
- CNTN2 | c.1957T>A p.W653R | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59351665; called by muse, mutect2
- CNTNAP5 | c.839A>T p.Q280L | Missense Mutation (SNP) | VAF 34/169 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.597); catalogued as COSV70498965; called by muse, mutect2, varscan2
- COL22A1 | c.4547C>A p.P1516H | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV57348708; called by mutect2, varscan2
- COL26A1 | c.251G>T p.R84L | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58121667, COSV58128628; called by muse, mutect2, varscan2
- COPS3 | c.502G>C p.D168H | Missense Mutation (SNP) | VAF 7/129 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.212); catalogued as COSV52006576; called by muse, mutect2
- CPN1 | c.937A>T p.K313* | Nonsense Mutation (SNP) | VAF 80/378 reads (21%) | catalogued as COSV64942574; called by muse, varscan2
- CPQ | c.1158G>T p.E386D | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.062); catalogued as COSV55153684; called by muse, mutect2, varscan2
- CRY1 | c.713G>A p.R238Q | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.041); catalogued as rs1008951536, COSV50486727, COSV99151081; called by muse, mutect2, varscan2
- CSMD3 | c.10376G>T p.W3459L (on ENST00000297405 / NM_001363185.1; = p.W3290L on NM_052900.3) | Missense Mutation (SNP) | VAF 7/123 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs1300679966, COSV52252323; called by muse, mutect2
- CSMD3 | c.944C>A p.P315Q | Missense Mutation (SNP) | VAF 35/171 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV52252359; called by muse, mutect2, varscan2
- CSRNP2 | c.943G>C p.E315Q | Missense Mutation (SNP) | VAF 12/217 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.271); catalogued as COSV50398528; called by muse, mutect2
- CSTF3 | c.788C>A p.P263H | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60613094; called by muse, mutect2, varscan2
- CTAGE6 | c.1180G>T p.D394Y | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV101417817; called by muse, mutect2, varscan2
- CTDSP1 | c.385G>T p.V129L | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV56090402; called by muse, mutect2, varscan2
- CUBN | c.4331G>T p.C1444F | Missense Mutation (SNP) | VAF 39/217 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64722106; called by muse, mutect2, varscan2
- CWC27 | c.530G>A p.R177K | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1471772868, COSV66887402; called by muse, mutect2, varscan2
- CYP2A7 | c.811T>C p.F271L | Missense Mutation (SNP) | VAF 12/159 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52503860; called by muse, mutect2
- DBNL | c.754G>C p.E252Q (on ENST00000448521 / NM_001014436.3; = p.E253Q on NM_014063.7) | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51979065; called by muse, mutect2
- DCAF8L1 | c.1507C>A p.Q503K | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as COSV71595416; called by muse, mutect2, varscan2
- DCST2 | c.1614G>C p.E538D | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV55053240; called by muse, mutect2, varscan2
- DDR1 | c.271C>G p.L91V | Missense Mutation (SNP) | VAF 27/226 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61323079; called by muse, mutect2, varscan2
- DDX54 | c.760G>C p.E254Q | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58373717, COSV58375062; called by muse, mutect2, varscan2
- DENND1A | c.1520G>C p.R507T | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as COSV65341093; called by muse, mutect2
- DENND4B | c.2569G>T p.A857S | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); catalogued as COSV63410618; called by muse, mutect2, varscan2
- DNAH3 | c.55C>A p.P19T | Missense Mutation (SNP) | VAF 20/239 reads (8%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV51786232; called by muse, mutect2
- DNAJC6 | c.1789G>T p.G597C | Missense Mutation (SNP) | VAF 11/218 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54778765; called by muse, mutect2
- DOP1B | c.559G>T p.G187W | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67694591; called by muse, mutect2, varscan2
- DOP1B | c.3576C>G p.F1192L | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67694596, COSV67694704; called by muse, mutect2, varscan2
- DRD1 | c.612C>A p.Y204* | Nonsense Mutation (SNP) | VAF 29/176 reads (16%) | catalogued as COSV67104662; called by muse, mutect2, varscan2
- DSG1 | c.1754C>T p.P585L | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV57137716; called by muse, mutect2, varscan2
- DUSP21 | c.463A>T p.N155Y | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV59134572; called by muse, mutect2, varscan2
- DYSF | c.1537G>T p.G513C | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50493533; called by muse, mutect2, varscan2
- DYTN | c.928C>A p.Q310K | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV71752602; called by muse, mutect2
- DZIP3 | c.2280G>C p.L760F | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV64312962; called by muse, mutect2, varscan2
- EDIL3 | c.509C>G p.S170* | Nonsense Mutation (SNP) | VAF 11/264 reads (4%) | catalogued as COSV56910163; called by muse, mutect2
- EDNRA | c.757G>T p.D253Y | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as COSV60095469, COSV60099076; called by muse, mutect2, varscan2
- EHHADH | c.1312C>G p.H438D | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as COSV51631794; called by muse, mutect2
- ELAVL2 | c.865G>C p.E289Q | Missense Mutation (SNP) | VAF 34/191 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV56366654; called by muse, mutect2, varscan2
- ELP3 | c.442A>T p.T148S | Missense Mutation (SNP) | VAF 18/149 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.034); catalogued as COSV56460496; called by muse, mutect2, varscan2
- ENOX1 | c.744C>G p.D248E | Missense Mutation (SNP) | VAF 52/264 reads (20%) | SIFT tolerated (0.86); PolyPhen benign (0.014); catalogued as COSV54909133; called by muse, mutect2, varscan2
- ENTPD6 | c.810G>T p.Q270H | Missense Mutation (SNP) | VAF 27/197 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV61751997, COSV61752574; called by muse, mutect2
- EPB41L4B | c.1999G>T p.E667* | Nonsense Mutation (SNP) | VAF 14/127 reads (11%) | catalogued as COSV63124285; called by muse, mutect2, varscan2
- ERBB4 | c.3442G>T p.E1148* | Nonsense Mutation (SNP) | VAF 19/142 reads (13%) | catalogued as COSV61506728; called by muse, mutect2, varscan2
- ERN2 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0.01); catalogued as rs1419273101, COSV56837499; called by muse, mutect2
- FAM135B | c.562G>T p.G188C | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52740594; called by muse, mutect2, varscan2
- FAM199X | c.340G>C p.E114Q | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.792); catalogued as COSV72419958; called by muse, mutect2
- FAM71B | c.1508G>A p.S503N | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV57228289, COSV57230093; called by muse, mutect2, varscan2
- FAM98C | c.1007G>T p.G336V | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); catalogued as COSV53039342; called by muse, mutect2, varscan2
- FARS2 | c.1052A>T p.K351M | Missense Mutation (SNP) | VAF 41/173 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.085); catalogued as COSV51171586; called by muse, mutect2, varscan2
- FBXO40 | c.273C>G p.S91R | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100573344, COSV57521872, COSV57525984; called by muse, mutect2
- FBXO40 | c.1306G>T p.E436* | Nonsense Mutation (SNP) | VAF 18/152 reads (12%) | catalogued as COSV57525992, COSV57526225; called by muse, mutect2, varscan2
- FCHO2 | c.585G>A p.M195I | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as rs377489605; called by muse, mutect2, varscan2
- FIG4 | c.656G>T p.G219V | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.705); catalogued as rs1347702545, COSV57786720; called by muse, mutect2, varscan2
- FLG | c.2878G>A p.E960K | Missense Mutation (SNP) | VAF 42/636 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as COSV64245083; called by muse, mutect2
- FLG | c.968G>T p.G323V | Missense Mutation (SNP) | VAF 65/297 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777209615, COSV64245088; called by muse, mutect2, varscan2
- FLG2 | c.613A>T p.R205* | Nonsense Mutation (SNP) | VAF 47/314 reads (15%) | catalogued as COSV66167444, COSV66170995; called by muse, mutect2, varscan2
- FMN2 | c.4175C>T p.S1392F | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60442197; called by muse, mutect2, varscan2
- FMO3 | c.109A>T p.I37F | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.17); catalogued as COSV63007961; called by muse, mutect2
- FRMPD1 | c.2371T>A p.S791T | Missense Mutation (SNP) | VAF 25/187 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.039); catalogued as COSV66701535; called by muse, mutect2, varscan2
- FUBP1 | c.1520C>T p.P507L | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV53935016; called by muse, mutect2
- GALNT13 | c.769G>T p.G257C | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101222619, COSV67230444; called by muse, mutect2, varscan2
- GBA | c.1205A>G p.Y402C | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs76228122, CM052241, COSV59170507; called by muse, varscan2
- GCN1 | c.1346G>C p.C449S | Missense Mutation (SNP) | VAF 42/140 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as COSV56111612; called by muse, mutect2, varscan2
- GJA4 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 23/242 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.104); catalogued as rs774721432, COSV60725778; called by muse, mutect2
- GLI3 | c.3854C>A p.P1285H | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as COSV67891973; called by muse, mutect2, varscan2
- GON4L | c.5497G>A p.G1833R | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs541780927, COSV55198637; called by muse, mutect2, varscan2
- GPATCH1 | c.2229A>T p.E743D | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV50120782; called by muse, mutect2, varscan2
- GPCPD1 | c.559G>C p.E187Q | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.69); catalogued as COSV66831382; called by muse, mutect2, varscan2
- GPR146 | c.886T>C p.Y296H | Missense Mutation (SNP) | VAF 10/139 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.75); catalogued as COSV52466731; called by muse, mutect2
- GPRC6A | c.2159C>A p.T720K | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV59954754; called by muse, mutect2, varscan2
- GRIA2 | c.1383C>A p.Y461* | Nonsense Mutation (SNP) | VAF 10/48 reads (21%) | catalogued as COSV52398651; called by muse, mutect2, varscan2
- GRIN1 | c.106C>G p.R36G | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.059); catalogued as COSV59298889; called by muse, mutect2, varscan2
- GRIN2B | c.2554G>T p.G852C | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101662940; called by muse, mutect2, varscan2
- GRIN2B | c.905C>A p.T302N | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.92); catalogued as rs1321033549, COSV74206894, COSV74207228; called by muse, mutect2, varscan2
- GRM8 | c.2050G>A p.V684I | Missense Mutation (SNP) | VAF 39/163 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.444); catalogued as COSV58848101; called by muse, mutect2, varscan2
- H2AC4 | c.169G>T p.E57* | Nonsense Mutation (SNP) | VAF 11/75 reads (15%) | catalogued as COSV52518518, COSV52519334; called by muse, mutect2
- H3-4 | c.137C>A p.T46K | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV64210620, COSV64210829; called by muse, mutect2, varscan2
- HCFC1R1 | c.344G>T p.R115L | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.902); catalogued as rs371111252, COSV99560435; called by muse, mutect2, varscan2
- HEBP1 | c.203G>A p.G68D | Missense Mutation (SNP) | VAF 25/225 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs778341967, COSV50009616; called by muse, mutect2, varscan2
- HEPACAM | c.663C>A p.N221K | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV53431216; called by muse, mutect2, varscan2
- HJV | c.300C>A p.D100E | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60952764; called by muse, mutect2, varscan2
- HLA-DQA2 | c.399T>A p.C133* | Nonsense Mutation (SNP) | VAF 34/188 reads (18%) | catalogued as rs1236594198, COSV66566103; called by muse, mutect2, varscan2
- HSPA8 | c.352G>T p.E118* | Nonsense Mutation (SNP) | VAF 10/55 reads (18%) | catalogued as COSV57085037; called by muse, mutect2, varscan2
- HTT | c.6414G>T p.S2138= | Splice Region (SNP) | VAF 32/224 reads (14%) | catalogued as rs547119123, COSV61865945; called by muse, varscan2
- HTT | c.8521G>C p.E2841Q | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61864625; called by muse, mutect2
- HYDIN | c.5626C>T p.R1876W | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1189741059, COSV59269613; called by muse, mutect2, varscan2
- HYDIN | c.261+2T>A p.X87_splice | Splice Site (SNP) | VAF 20/183 reads (11%) | catalogued as COSV55492656; called by muse, mutect2
- IBA57 | c.844G>T p.V282F | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.395); catalogued as COSV64511394; called by muse, mutect2, varscan2
- ID1 | c.64G>T p.G22C | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.976); catalogued as COSV101076693; called by muse, mutect2
- IFIT1B | c.189C>A p.H63Q | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1241113290, COSV65663282, COSV65663606; called by muse, mutect2, varscan2
- IFT52 | c.1118A>T p.K373M | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV65975638; called by muse, mutect2, varscan2
- IGKV1D-16 | c.348C>A p.Y116* | Nonsense Mutation (SNP) | VAF 17/93 reads (18%) | catalogued as rs761846741; called by muse, mutect2, varscan2
- IGSF1 | c.3619G>A p.E1207K | Missense Mutation (SNP) | VAF 30/257 reads (12%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.987); catalogued as COSV63837417, COSV63837545; called by muse, mutect2, varscan2
- IGSF3 | c.718G>A p.D240N | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59595151; called by muse, mutect2, varscan2
- IL1A | c.715C>A p.H239N | Missense Mutation (SNP) | VAF 16/153 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0.021); catalogued as COSV54519963; called by muse, mutect2
- IQGAP2 | c.3791C>A p.P1264H | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as COSV57177585; called by muse, varscan2
- ITPR1 | c.1152G>T p.R384S (on ENST00000354582; = p.R369S on NM_002222.7) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as COSV56994151; called by muse, mutect2, varscan2
- ITPRID1 | c.2098C>G p.L700V | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.89); PolyPhen benign (0.001); catalogued as rs1444986775, COSV60069438; called by muse, mutect2, varscan2
- JAK2 | c.811G>C p.E271Q | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV67638437; called by muse, mutect2, varscan2
- KALRN | c.2227G>T p.V743F | Missense Mutation (SNP) | VAF 28/195 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53773567; called by muse, mutect2, varscan2
- KDM5C | c.2953G>T p.E985* | Nonsense Mutation (SNP) | VAF 20/82 reads (24%) | catalogued as COSV100948848; called by muse, mutect2, varscan2
- KIF21B | c.389G>T p.R130L | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV59762335; called by muse, mutect2
- KLK1 | c.149G>T p.C50F | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56827724; called by muse, mutect2, varscan2
- KLK12 | c.260G>A p.R87Q | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.258); catalogued as rs372208750; called by muse, mutect2
- KMT2A | c.4852G>T p.A1618S | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV63289838; called by muse, mutect2
- KMT2C | c.6163G>T p.D2055Y | Missense Mutation (SNP) | VAF 23/139 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV51471955; called by muse, mutect2, varscan2
- KRT6A | c.1014G>T p.K338N | Missense Mutation (SNP) | VAF 81/278 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV58106620; called by muse, mutect2, varscan2
- LACC1 | c.599G>C p.G200A | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV57829500; called by muse, mutect2, varscan2
- LAMA2 | c.3787G>A p.E1263K | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.304); catalogued as COSV70337146, COSV70352184; called by muse, mutect2, varscan2
- LGI1 | c.1269A>T p.Q423H | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV65058728; called by muse, mutect2, varscan2
- LILRB2 | c.824G>T p.G275V | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58747100; called by muse, varscan2
- LLGL2 | c.190G>T p.V64L | Missense Mutation (SNP) | VAF 42/254 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV51376231; called by muse, mutect2, varscan2
- LMAN1 | c.1374G>A p.M458I | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV51828315; called by muse, varscan2
- LMBRD2 | c.41T>G p.F14C | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as COSV56951407; called by muse, mutect2, varscan2
- LPAR2 | c.883T>A p.Y295N | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV101345493, COSV68352427; called by muse, mutect2, varscan2
- LPCAT2 | c.1229G>T p.S410I | Missense Mutation (SNP) | VAF 10/145 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.076); catalogued as COSV50897383; called by muse, mutect2
- LPL | c.353A>T p.Q118L | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV60932094; called by muse, mutect2, varscan2
- LRGUK | c.1045G>A p.V349I | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.096); catalogued as rs754404912, COSV53634386; called by muse, mutect2
- LRP1B | c.499C>A p.Q167K | Missense Mutation (SNP) | VAF 26/191 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV67251081; called by muse, mutect2, varscan2
- LRP2 | c.7237C>A p.Q2413K | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT tolerated (0.64); PolyPhen benign (0.052); catalogued as COSV55564255; called by muse, mutect2, varscan2
- LRRC4B | c.526T>A p.Y176N | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.202); catalogued as COSV65350419; called by muse, mutect2, varscan2
- LRRC7 | c.3235G>T p.E1079* (on ENST00000651989 / NM_001370785.2; = p.E1046* on NM_001330635.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 8/69 reads (12%) | catalogued as COSV50443412, COSV99224952; called by muse, mutect2, varscan2
- LZTFL1 | c.430G>C p.G144R | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.534); catalogued as COSV56111967; called by muse, mutect2
- M1AP | c.529G>C p.E177Q | Missense Mutation (SNP) | VAF 10/170 reads (6%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.776); catalogued as COSV51846835; called by muse, mutect2
- MAGEA1 | c.559C>G p.Q187E | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV63118959, COSV63119251; called by muse, mutect2, varscan2
- MARVELD2 | c.1630C>G p.Q544E | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.559); catalogued as rs1345350883, COSV57780812, COSV57781526; called by muse, mutect2, varscan2
- MC2R | c.200C>A p.A67D | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59619383; called by muse, mutect2, varscan2
- MCC | c.1693G>A p.D565N | Missense Mutation (SNP) | VAF 29/191 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV56732604; called by muse, mutect2, varscan2
- MEFV | c.816C>A p.D272E | Missense Mutation (SNP) | VAF 22/270 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.037); catalogued as COSV54819881, COSV54825019; called by muse, mutect2
- MOGAT3 | c.652C>G p.L218V | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.354); catalogued as COSV56175834; called by muse, mutect2, varscan2
- MOS | c.553G>T p.V185F | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV61336709; called by muse, mutect2, varscan2
- MPZL2 | c.217G>C p.E73Q | Missense Mutation (SNP) | VAF 23/190 reads (12%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.505); catalogued as rs368432636; called by muse, mutect2, varscan2
- MSL2 | c.361G>T p.E121* | Nonsense Mutation (SNP) | VAF 16/204 reads (8%) | catalogued as COSV53867851; called by muse, mutect2
- MTA2 | c.82G>C p.E28Q | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as COSV53873475, COSV99604609; called by muse, mutect2
- MTHFR | c.1098C>G p.F366L | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as COSV64877938, COSV64878357; called by muse, mutect2, varscan2
- MUC16 | c.23174C>G p.P7725R | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.125); catalogued as COSV101198080, COSV67450285, COSV67480183; called by muse, mutect2, varscan2
- MYH1 | c.2441C>A p.S814Y | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.284); catalogued as COSV56853193; called by muse, mutect2, varscan2
- MYOM1 | c.4135A>T p.K1379* | Nonsense Mutation (SNP) | VAF 6/66 reads (9%) | catalogued as COSV55296764; called by muse, mutect2
- MYRIP | c.1534G>A p.E512K | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.594); catalogued as rs979372496, COSV56869665; called by muse, mutect2, varscan2
- MYT1 | c.314C>A p.S105* | Nonsense Mutation (SNP) | VAF 4/53 reads (8%) | catalogued as COSV100114106, COSV60500674; called by muse, mutect2
- NARS1 | c.1027C>G p.P343A | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT tolerated (0.78); PolyPhen benign (0.034); catalogued as COSV56877722; called by muse, mutect2, varscan2
- NCL | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.054); catalogued as COSV59546895; called by muse, mutect2
- NCLN | c.1564G>A p.A522T | Missense Mutation (SNP) | VAF 80/366 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55743155; called by muse, mutect2, varscan2
- NECTIN4 | c.1146G>T p.M382I | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.05); catalogued as COSV63513423; called by muse, varscan2
- NEK11 | c.1406C>T p.P469L | Missense Mutation (SNP) | VAF 14/284 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67280524; called by muse, mutect2
- NID2 | c.1079C>A p.T360N | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV99356062; called by muse, mutect2
- NKAP | c.59G>C p.R20T | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV65056653; called by muse, mutect2, varscan2
- NLGN4X | c.1746C>G p.Y582* | Nonsense Mutation (SNP) | VAF 29/104 reads (28%) | catalogued as COSV52028175; called by muse, mutect2, varscan2
- NLRP10 | c.1203C>A p.C401* | Nonsense Mutation (SNP) | VAF 5/47 reads (11%) | catalogued as COSV60781346; called by muse, mutect2
- NOP56 | c.563G>A p.R188H | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371285710; called by muse, varscan2
- NPLOC4 | c.1186C>T p.R396C | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs761872952, COSV58617943; called by muse, mutect2
- NPNT | c.720C>G p.C240W | Missense Mutation (SNP) | VAF 22/161 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59755636; called by muse, mutect2, varscan2
- NPY5R | c.378G>T p.L126F | Missense Mutation (SNP) | VAF 15/173 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.05); catalogued as COSV58453243; called by muse, mutect2
- NPY5R | c.379G>T p.V127F | Missense Mutation (SNP) | VAF 15/168 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV100642672; called by muse, mutect2
- NR1I3 | c.92G>T p.C31F | Missense Mutation (SNP) | VAF 28/151 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63468775; called by muse, mutect2, varscan2
- NRG3 | c.1076G>A p.R359K | Missense Mutation (SNP) | VAF 29/180 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.11); catalogued as rs145937983; called by muse, mutect2, varscan2
- NTNG1 | c.601G>T p.V201F | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.52); catalogued as COSV99635537, COSV99635744; called by muse, mutect2
- NTRK1 | c.892C>G p.H298D | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.342); catalogued as COSV62327262; called by muse, mutect2, varscan2
- NUDCD1 | c.576G>T p.L192F | Missense Mutation (SNP) | VAF 30/157 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.342); catalogued as COSV53458867; called by muse, mutect2, varscan2
- OCA2 | c.2451G>T p.M817I | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.378); catalogued as COSV62352319; called by mutect2, varscan2
- OGG1 | c.1070C>G p.P357R | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.169); catalogued as COSV56539626; called by muse, mutect2, varscan2
- OR1Q1 | c.716C>T p.S239F | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52918575; called by muse, mutect2
- OR2B11 | c.946T>A p.C316S | Missense Mutation (SNP) | VAF 61/397 reads (15%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV59510857; called by muse, mutect2, varscan2
- OR2D2 | c.191G>C p.C64S | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (1); PolyPhen possibly damaging (0.765); catalogued as COSV55057731; called by muse, mutect2, varscan2
- OR2L13 | c.112T>A p.S38T | Missense Mutation (SNP) | VAF 31/211 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV63557327; called by muse, mutect2, varscan2
- OR4C13 | c.247T>C p.S83P | Missense Mutation (SNP) | VAF 38/239 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.836); catalogued as COSV101634158, COSV73648840; called by muse, mutect2, varscan2
- OR4K5 | c.443C>T p.S148F | Missense Mutation (SNP) | VAF 24/578 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV60004389; called by muse, mutect2
- OR52B2 | c.445G>T p.A149S | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.205); catalogued as rs963656822, COSV73209485; called by muse, mutect2, varscan2
- OR5AS1 | c.826G>C p.V276L | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.013); catalogued as COSV57982550; called by mutect2, varscan2
- OR5T3 | c.579G>T p.M193I | Missense Mutation (SNP) | VAF 45/311 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57379345, COSV57381362, COSV57381812; called by muse, mutect2, varscan2
- OR7D4 | c.635C>A p.A212D | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.222); catalogued as COSV58072125; called by muse, mutect2, varscan2
- OR9A2 | c.364G>T p.V122L | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as rs971977288, COSV63306939; called by muse, mutect2, varscan2
- OSBPL2 | c.496G>C p.D166H (on ENST00000313733 / NM_144498.4; = p.D154H on NM_014835.4) | Missense Mutation (SNP) | VAF 11/125 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV58218450; called by muse, mutect2
- OSBPL6 | c.1540G>T p.D514Y | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV51924527; called by muse, mutect2, varscan2
- OTOF | c.2281C>G p.R761G (on ENST00000272371 / NM_194248.3; = p.R14G on NM_004802.4) | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.129); catalogued as COSV55508691, COSV55511066; called by muse, mutect2, varscan2
- PARP6 | c.757G>T p.V253F | Missense Mutation (SNP) | VAF 44/249 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.328); catalogued as COSV99535836; called by muse, mutect2, varscan2
- PARP6 | c.757-1G>A p.X253_splice | Splice Site (SNP) | VAF 43/246 reads (17%) | catalogued as COSV99535844; called by muse, mutect2, varscan2
- PCDH1 | c.3068G>T p.R1023L | Missense Mutation (SNP) | VAF 29/189 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); catalogued as COSV54611745, COSV54617061; called by muse, mutect2, varscan2
- PCDHA1 | c.1636G>T p.G546C | Missense Mutation (SNP) | VAF 22/169 reads (13%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.049); catalogued as COSV65375781; called by muse, mutect2, varscan2
- PCDHA6 | c.1449C>A p.D483E | Missense Mutation (SNP) | VAF 9/160 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100971799, COSV65344704, COSV65346009; called by muse, mutect2
- PCDHB13 | c.1874G>T p.R625L | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as rs1183119804, COSV99506876; called by muse, mutect2, varscan2
- PCDHB15 | c.495T>A p.N165K | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV51174859; called by muse, mutect2, varscan2
- PCDHB2 | c.1529C>T p.A510V | Missense Mutation (SNP) | VAF 11/294 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.379); catalogued as COSV50620512; called by muse, mutect2
- PCDHGA12 | c.2087C>T p.A696V | Missense Mutation (SNP) | VAF 18/249 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as rs1312403897, COSV52759326; called by muse, mutect2
- PCDHGA2 | c.1693C>T p.P565S | Missense Mutation (SNP) | VAF 32/289 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV53912789; called by muse, mutect2, varscan2
- PCDHGB3 | c.446G>C p.G149A | Missense Mutation (SNP) | VAF 26/247 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV53972715; called by muse, mutect2, varscan2
- PCLO | c.3649G>C p.E1217Q | Missense Mutation (SNP) | VAF 6/97 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.107); catalogued as COSV100436951, COSV61651697; called by muse, mutect2
- PCNX1 | c.1637C>A p.S546Y | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.853); catalogued as rs749367790, COSV53098172, COSV53100738; called by muse, mutect2
- PCNX1 | c.4090C>G p.P1364A | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53098182; called by muse, mutect2, varscan2
- PCNX4 | c.1049A>T p.H350L (on ENST00000406854 / NM_001330177.2; = p.H116L on NM_022495.5) | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV58306171; called by muse, mutect2, varscan2
- PDYN | c.620A>G p.Y207C | Missense Mutation (SNP) | VAF 28/216 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772099096, COSV54102215, COSV54102756; called by muse, mutect2, varscan2
- PFKL | c.1211T>G p.I404S | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV62464503; called by muse, mutect2, varscan2
- PHEX | c.1557C>G p.F519L | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV65077359; called by muse, mutect2
- PHF3 | c.5527C>G p.P1843A | Missense Mutation (SNP) | VAF 11/277 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV50328314; called by muse, mutect2
- PIGK | c.414G>T p.R138S | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63062904; called by muse, mutect2
- PIK3CG | c.269G>T p.R90L | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV100782625, COSV63245515; called by muse, mutect2
- PIK3R2 | c.1532G>T p.R511L | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.779); catalogued as COSV99717245; called by muse, mutect2, varscan2
- PIP5KL1 | c.587G>T p.G196V | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.762); catalogued as COSV55945063; called by muse, mutect2
- PKD1L1 | c.1871G>T p.W624L | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56972173; called by muse, mutect2, varscan2
- PKD2 | c.985G>T p.G329* | Nonsense Mutation (SNP) | VAF 13/66 reads (20%) | catalogued as COSV99416964; called by muse, mutect2, varscan2
- PKD2 | c.986G>T p.G329V | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs1388722678, COSV99416971; called by muse, mutect2, varscan2
- PKN2 | c.466G>C p.E156Q | Missense Mutation (SNP) | VAF 31/208 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.653); catalogued as COSV60133284; called by muse, mutect2, varscan2
- PLA1A | c.1244T>C p.I415T | Missense Mutation (SNP) | VAF 30/201 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.154); catalogued as COSV56332972; called by muse, mutect2, varscan2
- PLCB1 | c.796C>G p.L266V | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.608); catalogued as COSV62060297; called by muse, mutect2, varscan2
- PLEKHA5 | c.3191A>T p.Q1064L | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as COSV54707130; called by muse, mutect2
- PLXNA4 | c.4681G>A p.A1561T | Missense Mutation (SNP) | VAF 23/152 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.404); catalogued as COSV58115431; called by muse, mutect2, varscan2
- POMT2 | c.657G>T p.R219S | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.326); catalogued as COSV55072510; called by muse, mutect2
- POTEE | c.377G>A p.S126N | Missense Mutation (SNP) | VAF 29/141 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.235); catalogued as COSV58237617; called by muse, mutect2, varscan2
- PPM1G | c.1156A>G p.M386V | Missense Mutation (SNP) | VAF 29/243 reads (12%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.893); catalogued as rs1195738297, COSV59770782; called by muse, mutect2, varscan2
- PRAMEF17 | c.454G>C p.D152H | Missense Mutation (SNP) | VAF 34/382 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.437); catalogued as rs1045556755, COSV65816321, COSV65816525; called by muse, mutect2
- PREB | c.1072G>C p.G358R | Missense Mutation (SNP) | VAF 23/282 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as rs768670860, COSV53207290; called by muse, mutect2
- PROSER1 | c.1619G>T p.G540V | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.526); catalogued as COSV61488769; called by muse, mutect2, varscan2
- PROSER3 | c.1415G>T p.G472V | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV99994472; called by muse, mutect2, varscan2
- PRRC2A | c.4651G>T p.A1551S | Missense Mutation (SNP) | VAF 17/234 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV65688108; called by muse, mutect2
- PRRX2 | c.662C>A p.P221H | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.204); catalogued as COSV65241592, COSV65242787; called by muse, mutect2, varscan2
- PRSS55 | c.856A>G p.T286A | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60808847; called by muse, mutect2
- PRUNE2 | c.6418G>A p.E2140K | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1171091959, COSV65044461; called by muse, mutect2, varscan2
- PSD4 | c.1699G>T p.E567* | Nonsense Mutation (SNP) | VAF 32/265 reads (12%) | catalogued as COSV55528442; called by muse, mutect2, varscan2
- PSG2 | c.109A>T p.T37S | Missense Mutation (SNP) | VAF 33/321 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.633); catalogued as COSV68885036; called by muse, mutect2, varscan2
- PSG8 | c.430C>T p.L144= | Splice Region (SNP) | VAF 42/392 reads (11%) | catalogued as rs1466865677, COSV60610769; called by muse, mutect2, varscan2
- PSMC6 | c.484-1G>T p.X162_splice (on ENST00000612399; = p.X148_splice on NM_002806.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 30/164 reads (18%) | catalogued as COSV71629082; called by muse, mutect2, varscan2
- PTPN14 | c.2870A>T p.E957V | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV65286073; called by muse, mutect2, varscan2
- PTPRC | c.1675G>T p.G559* | Nonsense Mutation (SNP) | VAF 14/236 reads (6%) | catalogued as COSV100722207, COSV61420393; called by muse, mutect2
- PTPRC | c.1676G>T p.G559V | Missense Mutation (SNP) | VAF 14/239 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV100722209; called by muse, mutect2
- PTPRU | c.205G>T p.G69C | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777175459, COSV60532897; called by muse, mutect2
- PUM1 | c.397C>T p.Q133* | Nonsense Mutation (SNP) | VAF 19/190 reads (10%) | catalogued as COSV57088846; called by muse, mutect2, varscan2
- PUS7 | c.259G>T p.D87Y | Missense Mutation (SNP) | VAF 35/285 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.564); catalogued as COSV62677482; called by muse, mutect2, varscan2
- RAB3GAP2 | c.342G>C p.M114I | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.514); catalogued as COSV52966552, COSV52966603; called by muse, mutect2, varscan2
- RAE1 | c.823G>T p.A275S | Missense Mutation (SNP) | VAF 46/260 reads (18%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.493); catalogued as COSV64798576; called by muse, mutect2, varscan2
- RBM14 | c.750G>T p.R250S | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV59559990; called by muse, mutect2, varscan2
- RFX6 | c.1714T>G p.S572A | Missense Mutation (SNP) | VAF 46/181 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as COSV60587310; called by muse, mutect2, varscan2
- RGMB | c.145C>T p.Q49* (on ENST00000513185 / NM_001366508.1; = p.Q90* on NM_001012761.3 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 16/309 reads (5%) | catalogued as COSV100374758; called by muse, mutect2
- RGS14 | c.62A>G p.D21G | Missense Mutation (SNP) | VAF 31/243 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV68771685; called by muse, mutect2, varscan2
- RHBDD2 | c.785A>T p.H262L | Missense Mutation (SNP) | VAF 44/272 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.066); catalogued as rs1554544342, COSV50087725; called by muse, mutect2, varscan2
- RIF1 | c.1078-1G>T p.X360_splice | Splice Site (SNP) | VAF 25/188 reads (13%) | catalogued as COSV54620846; called by muse, mutect2, varscan2
- RNF165 | c.274G>T p.D92Y | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.367); catalogued as COSV99491360; called by muse, mutect2, varscan2
- RRAGC | c.352C>G p.P118A | Missense Mutation (SNP) | VAF 25/212 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV65931809; called by muse, mutect2, varscan2
- RYR1 | c.4261G>A p.D1421N | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.973); catalogued as rs983725107, COSV62095303; called by muse, mutect2, varscan2
- SAGE1 | c.1683G>C p.L561F | Missense Mutation (SNP) | VAF 9/132 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV61015625; called by muse, mutect2
- SCAPER | c.2310G>T p.E770D | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.13); catalogued as COSV57747220; called by muse, mutect2, varscan2
- SCG2 | c.1162C>A p.P388T | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.927); catalogued as COSV59540195, COSV59541041; called by muse, mutect2, varscan2
- SCML1 | c.580C>T p.P194S (on ENST00000380041 / NM_001037540.3; = p.P167S on NM_006746.6) | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.048); catalogued as COSV66240914; called by muse, mutect2, varscan2
- SCN2A | c.2803G>A p.V935M | Missense Mutation (SNP) | VAF 30/272 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1559376986, COSV51849285; called by muse, mutect2, varscan2
- SCN8A | c.4281G>A p.K1427= | Splice Region (SNP) | VAF 8/39 reads (21%) | catalogued as COSV61987484; called by muse, mutect2, varscan2
- SCRT1 | c.658C>A p.L220M | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.62); PolyPhen benign (0.023); catalogued as COSV59781818; called by muse, mutect2, varscan2
- SDK1 | c.4046A>T p.Y1349F | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV67380460; called by muse, mutect2
- SEC23B | c.1109G>T p.G370V | Missense Mutation (SNP) | VAF 48/300 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52722226; called by muse, mutect2, varscan2
- SEPHS2 | c.935A>G p.H312R | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as COSV72100793; called by muse, mutect2, varscan2
- SERTAD3 | c.568A>G p.M190V | Missense Mutation (SNP) | VAF 11/161 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.107); catalogued as COSV59325516; called by muse, mutect2
- SGIP1 | c.1490T>C p.I497T | Missense Mutation (SNP) | VAF 47/292 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.395); catalogued as rs779853610, COSV52763505; called by muse, varscan2
- SHANK1 | c.719T>C p.I240T | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as COSV53256827; called by muse, mutect2, varscan2
- SHISA3 | c.593C>A p.T198N | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.017); catalogued as COSV59980332; called by muse, mutect2, varscan2
- SHPRH | c.134C>A p.P45Q | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.024); catalogued as COSV51614191; called by muse, mutect2, varscan2
- SI | c.1259A>T p.Q420L | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.979); catalogued as COSV52290520; called by muse, mutect2
- SIGLEC1 | c.2499G>T p.E833D | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.083); catalogued as COSV52468452; called by muse, mutect2, varscan2
- SIPA1L3 | c.4969G>C p.A1657P | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55919801; called by muse, mutect2
- SLAMF1 | c.640C>G p.P214A | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.094); catalogued as COSV52500679; called by muse, mutect2
- SLC17A8 | c.1088T>C p.M363T | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV60125322; called by muse, mutect2, varscan2
- SLC24A2 | c.1814G>T p.C605F | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53870315; called by muse, mutect2, varscan2
- SLC26A4 | c.1024C>A p.P342T | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.065); catalogued as COSV55918398; called by muse, mutect2
- SLC30A10 | c.66C>G p.F22L | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.597); catalogued as rs747984224, COSV63073431, COSV99055448; called by mutect2, varscan2
- SLC30A9 | c.1102C>T p.R368C | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1273207910, COSV52557765; called by muse, mutect2
- SLC39A10 | c.1547G>C p.R516T | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated (0.91); PolyPhen benign (0.062); catalogued as COSV62766677, COSV62768438; called by muse, mutect2, varscan2
- SLC4A1 | c.2314C>A p.L772M | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.363); catalogued as COSV52261728; called by muse, mutect2, varscan2
- SLC4A3 | c.2276C>G p.A759G | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.317); catalogued as COSV56095934; called by muse, mutect2, varscan2
- SLC4A9 | c.1430T>C p.V477A (on ENST00000507527 / NM_001258428.2; = p.V453A on NM_031467.3) | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50200734; called by muse, mutect2, varscan2
- SLC52A3 | c.478G>T p.G160C | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54078477; called by muse, mutect2, varscan2
- SLC6A5 | c.2287G>T p.A763S | Missense Mutation (SNP) | VAF 9/170 reads (5%) | SIFT tolerated (0.68); PolyPhen benign (0.017); catalogued as COSV54229839; called by muse, mutect2
- SLC9C2 | c.101T>A p.L34H | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62947448; called by muse, mutect2, varscan2
- SLITRK2 | c.1534A>G p.K512E | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.05); catalogued as COSV59427345; called by muse, mutect2
- SLITRK6 | c.1733A>G p.Q578R | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0.015); catalogued as COSV68390995; called by muse, mutect2, varscan2
- SMARCAD1 | c.540G>C p.L180F | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as COSV62775470; called by muse, mutect2
- SMG1 | c.6136G>T p.D2046Y | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.172); catalogued as COSV67173526; called by muse, mutect2
- SND1 | c.695G>T p.R232L | Missense Mutation (SNP) | VAF 48/215 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as COSV61245318; called by muse, mutect2, varscan2
- SNED1 | c.320A>T p.D107V | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60029013; called by muse, mutect2
- SNX31 | c.1253C>A p.S418* | Nonsense Mutation (SNP) | VAF 8/60 reads (13%) | catalogued as rs779558029, COSV61264158; called by muse, mutect2, varscan2
- SOCS2 | c.472A>G p.T158A | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.109); catalogued as COSV61392403; called by muse, mutect2, varscan2
- SOS2 | c.2285A>T p.H762L | Missense Mutation (SNP) | VAF 23/249 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.077); catalogued as COSV53571008; called by muse, mutect2
- SP3 | c.544C>G p.Q182E | Missense Mutation (SNP) | VAF 17/483 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV59469560; called by muse, mutect2
- SP4 | c.1747G>T p.G583* | Nonsense Mutation (SNP) | VAF 10/75 reads (13%) | catalogued as COSV56024976; called by muse, mutect2, varscan2
- SPAG5 | c.2197G>A p.D733N | Missense Mutation (SNP) | VAF 51/278 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.167); catalogued as rs1407911656, COSV58803172, COSV58803560; called by muse, mutect2, varscan2
- SPATA22 | c.1010C>A p.S337Y | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.015); catalogued as COSV52153570; called by muse, mutect2, varscan2
- SPHKAP | c.2087G>C p.R696T | Missense Mutation (SNP) | VAF 52/327 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV60887930; called by muse, mutect2, varscan2
- SPTBN1 | c.6026G>A p.R2009Q | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); catalogued as rs762333666, COSV61691243; called by muse, mutect2, varscan2
- SRRT | c.447G>A p.M149I | Missense Mutation (SNP) | VAF 15/181 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV61453677; called by muse, mutect2
- SS18 | c.872A>T p.Y291F | Missense Mutation (SNP) | VAF 21/230 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.104); catalogued as COSV52262660, COSV52264197; called by muse, mutect2
- STK16 | c.514C>G p.Q172E | Missense Mutation (SNP) | VAF 7/175 reads (4%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs1389446512, COSV50279812; called by muse, mutect2
- SUGP2 | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 15/138 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.283); catalogued as rs1437455707, COSV58262119; called by muse, mutect2, varscan2
- SURF1 | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 30/369 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.318); catalogued as rs782358655, COSV59871279; called by muse, mutect2
- SYCP1 | c.2321A>T p.K774M | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV65699652; called by muse, mutect2, varscan2
- SYNJ2 | c.260C>T p.S87F | Missense Mutation (SNP) | VAF 9/124 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62897565, COSV62900141; called by muse, mutect2
- SYT14 | c.340G>T p.A114S | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV55059285; called by muse, mutect2, varscan2
- SYTL4 | c.1010C>T p.T337M | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.173); catalogued as rs769639083, COSV52168089; called by muse, mutect2, varscan2
- TASP1 | c.978G>T p.K326N | Missense Mutation (SNP) | VAF 44/209 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.376); catalogued as COSV61814555; called by muse, mutect2, varscan2
- TBC1D15 | c.1960C>G p.P654A | Missense Mutation (SNP) | VAF 13/293 reads (4%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.013); catalogued as COSV59851254; called by muse, mutect2
- TBC1D31 | c.2209G>A p.E737K | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV54868821; called by muse, mutect2
- TENM1 | c.217+1G>T p.X73_splice | Splice Site (SNP) | VAF 26/74 reads (35%) | catalogued as COSV100949285; called by muse, mutect2, varscan2
- TENM3 | c.2020C>T p.P674S | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as COSV69314261; called by muse, mutect2, varscan2
- TEP1 | c.4893G>T p.Q1631H | Missense Mutation (SNP) | VAF 14/193 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV52996395; called by muse, mutect2
- TET3 | c.5079C>G p.F1693L | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.484); catalogued as COSV69644379; called by muse, mutect2, varscan2
- TF | c.787G>T p.A263S | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV53922097; called by muse, mutect2, varscan2
- TFAP2D | c.626A>G p.D209G | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.147); catalogued as COSV50437093; called by muse, mutect2, varscan2
- TFB1M | c.676G>T p.G226C | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51642812; called by muse, mutect2, varscan2
- TFB2M | c.733G>C p.D245H | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0.027); catalogued as COSV63625054; called by muse, mutect2, varscan2
- TFDP2 | c.661G>C p.E221Q (on ENST00000489671 / NM_001178139.2; = p.E161Q on NM_006286.5) | Missense Mutation (SNP) | VAF 20/214 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.419); catalogued as COSV57709582; called by muse, mutect2
- TFG | c.1003C>T p.Q335* | Nonsense Mutation (SNP) | VAF 15/105 reads (14%) | catalogued as COSV52544513; called by muse, mutect2, varscan2
- THG1L | c.333C>G p.F111L | Missense Mutation (SNP) | VAF 13/239 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.115); catalogued as COSV51453341; called by muse, mutect2
- THSD7B | c.2729C>A p.S910Y | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.269); catalogued as COSV55714637; called by muse, mutect2, varscan2
- TIPIN | c.312C>G p.I104M | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.484); catalogued as COSV56020535; called by muse, mutect2, varscan2
- TLE1 | c.1402G>T p.G468* | Nonsense Mutation (SNP) | VAF 14/138 reads (10%) | catalogued as COSV64722083, COSV64723837; called by muse, mutect2, varscan2
- TLN2 | c.5167C>T p.R1723W | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs146711240; called by muse, mutect2, varscan2
- TMED4 | c.639G>C p.Q213H | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56942243; called by muse, mutect2, varscan2
- TMEM132B | c.2094A>T p.E698D | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54761805; called by muse, mutect2, varscan2
- TMEM64 | c.842G>T p.G281V | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69128013; called by muse, mutect2, varscan2
- TMPRSS15 | c.418C>A p.L140M | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.823); catalogued as COSV53034418, COSV53044339, COSV53044938; called by muse, mutect2, varscan2
- TMPRSS7 | c.1771G>A p.E591K (on ENST00000452346; = p.E465K on NM_001042575.2) | Missense Mutation (SNP) | VAF 8/207 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV69981917; called by muse, mutect2
- TNC | c.5608G>C p.E1870Q | Missense Mutation (SNP) | VAF 9/129 reads (7%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.925); catalogued as COSV60787791; called by muse, mutect2
- TOR2A | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as COSV60161618; called by muse, mutect2, varscan2
- TP53 | c.1051A>T p.K351* | Nonsense Mutation (SNP) | VAF 8/63 reads (13%) | catalogued as COSV52745104, COSV52944131; called by muse, mutect2, varscan2
- TRAPPC10 | c.2258A>G p.Y753C | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV52379561; called by muse, mutect2, varscan2
- TREML4 | c.463G>C p.E155Q | Missense Mutation (SNP) | VAF 13/155 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV58385755; called by muse, mutect2
- TRERF1 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 28/314 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.871); catalogued as COSV61675137; called by muse, mutect2
- TRIM36 | c.1247-1G>T p.X416_splice | Splice Site (SNP) | VAF 5/30 reads (17%) | catalogued as COSV99142280; called by mutect2, varscan2
- TRIP6 | c.1322C>G p.S441C | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52342590, COSV52343236; called by muse, mutect2
- TRPC4 | c.243G>T p.E81D | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as COSV100156129; called by muse, mutect2
- TRRAP | c.3334G>T p.E1112* | Nonsense Mutation (SNP) | VAF 34/127 reads (27%) | catalogued as COSV62850120; called by muse, mutect2, varscan2
- TRRAP | c.11398G>A p.E3800K (on ENST00000359863 / NM_001244580.1; = p.E3771K on NM_003496.3) | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as COSV62816454; called by muse, mutect2
- TTC8 | c.1021C>A p.H341N (on ENST00000338104 / NM_001288781.1; = p.H325N on NM_144596.4) | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV57628961; called by muse, mutect2, varscan2
- TTL | c.163G>T p.E55* | Nonsense Mutation (SNP) | VAF 28/247 reads (11%) | catalogued as COSV51975674; called by muse, mutect2, varscan2
- TTN | c.98062G>C p.A32688P (on ENST00000591111; = p.A25264P on NM_003319.4) | Missense Mutation (SNP) | VAF 9/65 reads (14%) | PolyPhen probably damaging (0.955); catalogued as COSV60207279; called by muse, mutect2, varscan2
- TTN | c.84638G>T p.G28213V (on ENST00000591111; = p.G20789V on NM_003319.4) | Missense Mutation (SNP) | VAF 39/318 reads (12%) | PolyPhen probably damaging (1); catalogued as rs1307295832, COSV60207323; called by muse, mutect2, varscan2
- TTN | c.72587C>A p.P24196Q (on ENST00000591111; = p.P16772Q on NM_003319.4) | Missense Mutation (SNP) | VAF 26/140 reads (19%) | PolyPhen possibly damaging (0.563); catalogued as COSV60207366, COSV60240510; called by muse, mutect2, varscan2
- TTN | c.57523C>T p.P19175S (on ENST00000591111; = p.P11751S on NM_003319.4) | Missense Mutation (SNP) | VAF 31/186 reads (17%) | PolyPhen possibly damaging (0.859); catalogued as COSV60207414; called by muse, mutect2, varscan2
- TTN | c.3070G>T p.V1024F (on ENST00000591111; = p.V978F on NM_003319.4) | Missense Mutation (SNP) | VAF 11/72 reads (15%) | PolyPhen probably damaging (0.948); catalogued as COSV60207473; called by muse, mutect2, varscan2
- UBE3B | c.1743G>T p.E581D | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99783715; called by muse, mutect2, varscan2
- UBN2 | c.539C>T p.A180V | Missense Mutation (SNP) | VAF 25/209 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV99943702; called by muse, mutect2, varscan2
- UBOX5 | c.331G>A p.D111N | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as COSV53907724; called by muse, mutect2, varscan2
- UCKL1 | c.202G>C p.E68Q | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.67); catalogued as COSV62403383; called by muse, mutect2
- UROC1 | c.903-1G>T p.X301_splice | Splice Site (SNP) | VAF 23/128 reads (18%) | catalogued as COSV52036375; called by muse, mutect2, varscan2
- USP43 | c.2032G>A p.D678N | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV53305202; called by muse, mutect2, varscan2
- VAV1 | c.970G>T p.D324Y | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58387907; called by muse, mutect2, varscan2
- VPS37D | c.454C>T p.Q152* | Nonsense Mutation (SNP) | VAF 15/48 reads (31%) | catalogued as COSV61446735; called by muse, mutect2, varscan2
- VPS8 | c.1312G>T p.V438L (on ENST00000625842 / NM_001349294.1; = p.V436L on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/200 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54991587; called by muse, mutect2, varscan2
- WDR5 | c.317C>G p.S106* | Nonsense Mutation (SNP) | VAF 19/123 reads (15%) | catalogued as COSV62273419; called by muse, mutect2, varscan2
- WDR5 | c.437C>G p.S146* | Nonsense Mutation (SNP) | VAF 12/107 reads (11%) | catalogued as COSV100681826, COSV62273423; called by muse, mutect2, varscan2
- WDR90 | c.4801G>T p.V1601F | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV53472830; called by muse, mutect2, varscan2
- WNK1 | c.6576C>G p.D2192E (on ENST00000315939 / NM_018979.4; = p.D1944E on NM_014823.3) | Missense Mutation (SNP) | VAF 36/527 reads (7%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as COSV60040063; called by muse, mutect2
- WNT16 | c.886G>C p.E296Q (on ENST00000222462 / NM_057168.2; = p.E286Q on NM_016087.2) | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.194); catalogued as COSV55976842; called by muse, mutect2, varscan2
- WNT7A | c.667G>T p.E223* | Nonsense Mutation (SNP) | VAF 23/125 reads (18%) | catalogued as COSV53200821, COSV99540882; called by muse, mutect2, varscan2
- WWC1 | c.1861G>A p.A621T | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1192324622, COSV54655024; called by muse, mutect2
- XIRP2 | c.8656G>A p.V2886I (on ENST00000628543; = p.V3061I on NM_152381.6) | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54718779; called by muse, mutect2, varscan2
- ZBED9 | c.3839G>T p.G1280V | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV71729630; called by muse, mutect2, varscan2
- ZFHX4 | c.6474G>T p.Q2158H | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51476579; called by muse, mutect2, varscan2
- ZNF148 | c.2193G>T p.Q731H | Missense Mutation (SNP) | VAF 13/142 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as rs1226565472, COSV62306169; called by muse, mutect2
- ZNF236 | c.4703C>T p.T1568M | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs771786580, COSV99469388; called by muse, mutect2, varscan2
- ZNF285 | c.1509A>T p.Q503H | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV58410062; called by muse, mutect2
- ZNF358 | c.1153G>T p.G385C | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV51178151; called by mutect2, varscan2
- ZNF407 | c.3722G>T p.G1241V | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.082); catalogued as rs1568136720, COSV99995051; called by muse, mutect2
- ZNF425 | c.790C>T p.H264Y | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV65202005, COSV65202572; called by muse, mutect2, varscan2
- ZNF454 | c.494G>C p.S165T | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as COSV100195546, COSV60769432; called by muse, mutect2
- ZNF497 | c.76A>T p.T26S | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV54052375; called by muse, mutect2, varscan2
- ZNF567 | c.937G>A p.E313K (on ENST00000536254 / NM_001322913.1; = p.E282K on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV100658651; called by muse, mutect2
- ZNF668 | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs773506838, COSV56216959; called by muse, mutect2, varscan2
- ZNF791 | c.955G>A p.E319K | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.078); catalogued as COSV58482009; called by muse, mutect2
- ZNF846 | c.649A>T p.I217L | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV67412336; called by muse, mutect2, varscan2
- ZP4 | c.934C>A p.P312T | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as rs1301890553, COSV63912822; called by muse, mutect2, varscan2
- CPZ | c.906+1_906+5del p.X302_splice (on ENST00000360986 / NM_001014447.3; = p.X291_splice on NM_003652.3) | Splice Site (DEL) | VAF 6/27 reads (22%) | called by mutect2, pindel, varscan2
- GDF10 | c.1357del p.V453Sfs*12 | Frame Shift Del (DEL) | VAF 34/194 reads (18%) | called by mutect2, pindel, varscan2
- GPR37 | c.489del p.R164Vfs*7 | Frame Shift Del (DEL) | VAF 33/214 reads (15%) | called by mutect2, pindel, varscan2
- KIAA1210 | c.3652del p.A1218Hfs*41 | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | called by mutect2, pindel, varscan2
- LRRC37B | c.2797del p.R933Gfs*30 | Frame Shift Del (DEL) | VAF 14/112 reads (13%) | called by mutect2, pindel, varscan2
- MRC1 | c.520T>A p.F174I | Missense Mutation (SNP) | VAF 45/423 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- OGFOD2 | c.267C>A p.Y89* (on ENST00000228922 / NM_001304833.1; = p.Y29* on NM_024623.3) | Nonsense Mutation (SNP) | VAF 8/76 reads (11%) | called by mutect2, varscan2
- OR6C6 | c.67dup p.I23Nfs*41 | Frame Shift Ins (INS) | VAF 26/142 reads (18%) | called by pindel, varscan2
- PCDHB16 | c.521del p.P174Qfs*8 | Frame Shift Del (DEL) | VAF 9/65 reads (14%) | called by mutect2, pindel, varscan2
- RIMBP2 | c.1654G>T p.V552L | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2
- RRBP1 | c.270del p.N91Mfs*2 | Frame Shift Del (DEL) | VAF 8/20 reads (40%) | called by mutect2, varscan2
- TRBV2 | c.241G>C p.D81H | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- USP9X | c.7022del p.L2341Cfs*5 | Frame Shift Del (DEL) | VAF 27/102 reads (26%) | called by mutect2, pindel, varscan2
- ACSS3 | c.393C>T p.I131= | Silent (SNP) | VAF 27/126 reads (21%) | catalogued as COSV54096710; called by muse, mutect2, varscan2
- ACTB | c.63C>T p.F21= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as rs370972197, COSV59319554, COSV59319716; ClinVar: likely benign; called by muse, mutect2, varscan2
- ADAM7 | c.2238C>T p.I746= | Silent (SNP) | VAF 11/101 reads (11%) | catalogued as rs765791653, COSV51535930; called by muse, mutect2, varscan2
- ADAMTS3 | c.1413T>G p.L471= | Silent (SNP) | VAF 5/64 reads (8%) | catalogued as COSV54397165; called by muse, mutect2
- ADGRB3 | c.1143G>C p.P381= | Silent (SNP) | VAF 13/116 reads (11%) | catalogued as rs778446616, COSV65408486; called by muse, mutect2, varscan2
- ADGRL2 | c.1695G>A p.L565= | Silent (SNP) | VAF 30/98 reads (31%) | catalogued as COSV54670848, COSV54678211; called by muse, mutect2, varscan2
- ADTRP | c.207A>G p.R69= | Silent (SNP) | VAF 20/172 reads (12%) | catalogued as COSV57644693; called by muse, mutect2, varscan2
- AGTPBP1 | c.3264A>G p.V1088= (on ENST00000357081 / NM_001330701.2; = p.V1048= on NM_015239.2) | Silent (SNP) | VAF 37/171 reads (22%) | catalogued as COSV61274760; called by muse, mutect2, varscan2
- AHNAK2 | c.12666C>A p.P4222= | Silent (SNP) | VAF 18/165 reads (11%) | catalogued as COSV60922798; called by muse, mutect2, varscan2
- APOB | c.5694T>A p.S1898= | Silent (SNP) | VAF 19/174 reads (11%) | catalogued as COSV51944622; called by muse, mutect2, varscan2
- APOB | c.2862A>T p.P954= | Silent (SNP) | VAF 15/159 reads (9%) | catalogued as COSV51926018, COSV51944629; called by muse, mutect2, varscan2
- ARHGAP33 | c.1893G>A p.L631= | Silent (SNP) | VAF 18/206 reads (9%) | catalogued as COSV50137467; called by muse, mutect2
- ASPG | c.57C>A p.T19= | Silent (SNP) | VAF 10/78 reads (13%) | catalogued as rs753722069, COSV71934005; called by muse, mutect2, varscan2
- BEND2 | c.1638G>T p.L546= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as COSV101191836; called by muse, mutect2
- BOD1L1 | c.6324C>A p.T2108= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV50031057; called by muse, mutect2
- C11orf87 | c.99G>A p.T33= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as rs369219861; called by muse, mutect2, varscan2
- CASR | c.2748G>T p.T916= (on ENST00000490131; = p.T993= on NM_000388.4) | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as COSV56139506, COSV99949071; called by muse, mutect2, varscan2
- CCKBR | c.510C>T p.H170= | Silent (SNP) | VAF 3/39 reads (8%) | catalogued as COSV58103553; called by muse, mutect2
- CCN6 | c.291G>T p.G97= | Silent (SNP) | VAF 14/103 reads (14%) | catalogued as rs782261028, COSV57889919; called by muse, mutect2, varscan2
- CD72 | c.888A>G p.S296= | Silent (SNP) | VAF 15/191 reads (8%) | catalogued as COSV52411869; called by muse, mutect2
- CD93 | c.874C>A p.R292= | Silent (SNP) | VAF 18/245 reads (7%) | catalogued as COSV55665675, COSV55667177, COSV99849651; called by muse, mutect2
- CLDN15 | c.450G>A p.L150= | Silent (SNP) | VAF 7/124 reads (6%) | catalogued as COSV57659404; called by muse, mutect2
- CNTNAP2 | c.1323G>A p.K441= | Silent (SNP) | VAF 17/154 reads (11%) | catalogued as COSV100673818, COSV62222914, COSV62267893; called by muse, mutect2
- CNTROB | c.1959C>T p.P653= | Silent (SNP) | VAF 16/196 reads (8%) | catalogued as COSV66608811; called by muse, mutect2
- CPOX | c.900G>A p.L300= | Silent (SNP) | VAF 14/91 reads (15%) | catalogued as COSV51638954; called by muse, mutect2, varscan2
- CPVL | c.40C>T p.L14= | Silent (SNP) | VAF 7/73 reads (10%) | catalogued as COSV55300408, COSV55305504; called by muse, mutect2, varscan2
- CSKMT | c.678C>T p.F226= | Silent (SNP) | VAF 11/164 reads (7%) | catalogued as rs1439204489, COSV63473299; called by muse, mutect2
- CTNNA2 | c.2706T>A p.P902= (on ENST00000402739 / NM_001282597.3; = p.P854= on NM_004389.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/238 reads (5%) | catalogued as COSV58166075; called by muse, mutect2
- DCAF8L1 | c.558C>T p.F186= | Silent (SNP) | VAF 3/13 reads (23%) | catalogued as rs1179527579; called by muse, mutect2
- DCHS1 | c.381A>G p.V127= | Silent (SNP) | VAF 20/80 reads (25%) | catalogued as COSV55039422; called by muse, mutect2, varscan2
- DCTN5 | c.438C>T p.F146= | Silent (SNP) | VAF 15/94 reads (16%) | catalogued as COSV55615927; called by muse, mutect2, varscan2
- DIPK1C | c.1177C>A p.R393= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV100679902, COSV59725874; called by muse, mutect2, varscan2
- DLC1 | c.2730C>G p.L910= (on ENST00000276297 / NM_001348081.2; = p.L473= on NM_006094.5) | Silent (SNP) | VAF 9/67 reads (13%) | catalogued as COSV52316753; called by muse, mutect2, varscan2
- DLEU7 | c.348G>A p.A116= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV68548198; called by muse, mutect2, varscan2
- DMD | c.4155C>A p.S1385= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV63776040; called by muse, mutect2, varscan2
- DPH2 | c.528A>G p.L176= | Silent (SNP) | VAF 30/121 reads (25%) | catalogued as COSV52544277; called by muse, mutect2, varscan2
- DPY19L1 | c.1443T>A p.V481= | Silent (SNP) | VAF 21/147 reads (14%) | catalogued as COSV60583287; called by muse, mutect2, varscan2
- EGFL6 | c.984T>C p.S328= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as COSV63634569; called by muse, mutect2, varscan2
- EPHA6 | c.2112T>C p.D704= (on ENST00000389672 / NM_001080448.3; = p.D96= on NM_173655.4) | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as COSV67583921; called by muse, mutect2, varscan2
- EXOC3 | c.597G>T p.L199= | Silent (SNP) | VAF 8/116 reads (7%) | catalogued as COSV59267878; called by muse, mutect2
- FARSA | c.1362C>T p.V454= | Silent (SNP) | VAF 16/135 reads (12%) | catalogued as COSV53365353, COSV53367494; called by muse, mutect2, varscan2
- FMO1 | c.1122C>A p.P374= | Silent (SNP) | VAF 12/132 reads (9%) | catalogued as COSV61446867; called by muse, mutect2, varscan2
- FN3K | c.783C>T p.T261= | Silent (SNP) | VAF 24/237 reads (10%) | catalogued as rs1464774659, COSV56182612; called by muse, mutect2, varscan2
- FNDC3B | c.3432C>T p.P1144= | Silent (SNP) | VAF 11/102 reads (11%) | catalogued as rs180793348, COSV61046333; called by muse, mutect2, varscan2
- FRMD8 | c.813C>T p.F271= | Silent (SNP) | VAF 9/77 reads (12%) | catalogued as COSV58213310; called by muse, mutect2, varscan2
- GIMAP2 | c.312A>G p.P104= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as COSV56235878; called by muse, mutect2, varscan2
- GLG1 | c.1308G>C p.L436= | Silent (SNP) | VAF 29/195 reads (15%) | catalogued as COSV52671073; called by muse, mutect2, varscan2
- GLMN | c.297A>G p.P99= | Silent (SNP) | VAF 27/93 reads (29%) | catalogued as COSV64861092; called by muse, mutect2, varscan2
- GNAO1 | c.1053C>T p.C351= | Silent (SNP) | VAF 9/104 reads (9%) | catalogued as rs981002186, COSV52617472; called by muse, mutect2
- GPR26 | c.600C>T p.R200= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as rs1480192587, COSV52935312; called by mutect2, varscan2
- GTSE1 | c.1872C>G p.A624= | Silent (SNP) | VAF 26/194 reads (13%) | catalogued as COSV71889509; called by muse, mutect2, varscan2
- H1-2 | c.255G>A p.K85= | Silent (SNP) | VAF 25/158 reads (16%) | catalogued as rs1554149664, COSV59191504, COSV59191681; called by muse, mutect2, varscan2
- HIVEP2 | c.4137C>T p.V1379= | Silent (SNP) | VAF 5/71 reads (7%) | catalogued as COSV50029093; called by muse, mutect2
- INCENP | c.384G>T p.A128= | Silent (SNP) | VAF 16/142 reads (11%) | catalogued as COSV53918619; called by muse, mutect2
- ITPRID2 | c.1911G>T p.L637= | Silent (SNP) | VAF 18/153 reads (12%) | catalogued as COSV57474481; called by muse, mutect2, varscan2
- JADE2 | c.12G>A p.K4= | Silent (SNP) | VAF 12/108 reads (11%) | catalogued as COSV50923404; called by muse, mutect2, varscan2
- KCND3 | c.747C>T p.P249= | Silent (SNP) | VAF 4/58 reads (7%) | catalogued as COSV56185412; called by muse, mutect2
- KIAA1549 | c.3876G>T p.P1292= | Silent (SNP) | VAF 23/97 reads (24%) | catalogued as COSV54321811; called by muse, mutect2, varscan2
- KRT33B | c.243C>T p.N81= | Silent (SNP) | VAF 10/129 reads (8%) | catalogued as COSV52441746; called by muse, mutect2
- KYNU | c.231C>T p.G77= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as COSV51588019, COSV99933912; called by muse, mutect2
- LAMA5 | c.8286C>G p.L2762= | Silent (SNP) | VAF 8/177 reads (5%) | catalogued as COSV53365918; called by muse, mutect2
- LHX2 | c.951C>A p.A317= | Silent (SNP) | VAF 22/116 reads (19%) | catalogued as COSV65318797; called by muse, mutect2, varscan2
- LILRB1 | c.939C>G p.L313= (on ENST00000427581; = p.L277= on NM_006669.6) | Silent (SNP) | VAF 102/207 reads (49%) | catalogued as COSV61120242; called by muse, mutect2, varscan2
- LRP5 | c.1029G>A p.V343= | Silent (SNP) | VAF 15/91 reads (16%) | catalogued as rs1277360472, COSV53719982; called by muse, mutect2, varscan2
- LRRTM4 | c.927T>A p.S309= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV69141109; called by muse, mutect2, varscan2
- MAGEA10 | c.7C>A p.R3= | Silent (SNP) | VAF 29/124 reads (23%) | catalogued as COSV54885047; called by muse, mutect2, varscan2
- MAPK8IP3 | c.852C>T p.A284= | Silent (SNP) | VAF 12/96 reads (13%) | catalogued as rs775788314, COSV51716903, COSV99167595; called by muse, mutect2, varscan2
- MAT2A | c.495A>T p.A165= | Silent (SNP) | VAF 12/96 reads (13%) | catalogued as COSV52089451; called by muse, mutect2, varscan2
- MMP16 | c.493C>T p.L165= | Silent (SNP) | VAF 10/83 reads (12%) | catalogued as COSV54177856; called by muse, mutect2, varscan2
- MTDH | c.132G>C p.P44= | Silent (SNP) | VAF 7/113 reads (6%) | catalogued as COSV60345511; called by muse, mutect2
- NAGS | c.15G>A p.L5= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV53227940, COSV99517827; called by muse, mutect2
- NAPSA | c.174C>A p.A58= | Silent (SNP) | VAF 16/71 reads (23%) | catalogued as COSV53798406; called by muse, mutect2, varscan2
- NKX3-2 | c.861C>A p.R287= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV66711531, COSV66711889; called by muse, mutect2, varscan2
- NOD1 | c.744G>T p.L248= | Silent (SNP) | VAF 15/164 reads (9%) | catalogued as COSV56113812; called by muse, mutect2
- NOMO3 | c.2310A>G p.K770= | Silent (SNP) | VAF 34/369 reads (9%) | catalogued as COSV99530712; called by muse, mutect2, varscan2
- NPR2 | c.792A>T p.A264= | Silent (SNP) | VAF 14/112 reads (13%) | catalogued as COSV61313066; called by muse, mutect2, varscan2
- NRSN1 | c.69C>G p.R23= | Silent (SNP) | VAF 5/86 reads (6%) | catalogued as COSV65894016, COSV65894291; called by muse, mutect2
- NUP214 | c.5757T>C p.S1919= | Silent (SNP) | VAF 51/242 reads (21%) | catalogued as COSV63911489; called by muse, mutect2, varscan2
- OCRL | c.852A>G p.E284= | Silent (SNP) | VAF 25/144 reads (17%) | catalogued as COSV63981447; called by muse, mutect2, varscan2
- OLFML1 | c.60G>T p.L20= | Silent (SNP) | VAF 12/86 reads (14%) | catalogued as COSV61403160; called by muse, mutect2, varscan2
- OR10T2 | c.609C>T p.L203= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV57782441; called by muse, mutect2, varscan2
- OR13C9 | c.678C>G p.L226= | Silent (SNP) | VAF 16/84 reads (19%) | catalogued as rs1474706137, COSV52242941, COSV52243663; called by muse, mutect2, varscan2
- OR1L4 | c.417A>G p.P139= | Silent (SNP) | VAF 20/300 reads (7%) | catalogued as COSV52341052; called by muse, mutect2
- OR2A25 | c.453A>T p.G151= | Silent (SNP) | VAF 43/164 reads (26%) | catalogued as COSV101376360, COSV68717473; called by muse, mutect2, varscan2
- OR2T10 | c.357C>A p.A119= | Silent (SNP) | VAF 14/102 reads (14%) | catalogued as COSV57897558; called by muse, mutect2, varscan2
- OR4D9 | c.579C>T p.F193= | Silent (SNP) | VAF 21/191 reads (11%) | catalogued as COSV61434629; called by muse, mutect2, varscan2
- OR51T1 | c.111C>T p.Y37= | Silent (SNP) | VAF 12/244 reads (5%) | catalogued as COSV59026831; called by muse, mutect2
- OR5P3 | c.387C>T p.P129= | Silent (SNP) | VAF 23/147 reads (16%) | catalogued as rs926386244, COSV60429597; called by muse, mutect2, varscan2
- OR5T2 | c.528A>T p.S176= | Silent (SNP) | VAF 14/210 reads (7%) | catalogued as COSV57590278; called by muse, mutect2
- OR6K3 | c.294C>G p.L98= (on ENST00000368146; = p.L82= on NM_001005327.2) | Silent (SNP) | VAF 38/280 reads (14%) | catalogued as COSV63746105; called by muse, mutect2, varscan2
- OTUD6A | c.645A>G p.A215= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as COSV57973975; called by muse, mutect2, varscan2
- PBLD | c.711C>G p.L237= | Silent (SNP) | VAF 10/185 reads (5%) | catalogued as COSV53266771, COSV99515987; called by muse, mutect2
- PCDHA2 | c.2139C>T p.L713= | Silent (SNP) | VAF 12/250 reads (5%) | catalogued as COSV100973917, COSV65369328; called by muse, mutect2
- PCDHA4 | c.504C>T p.L168= | Silent (SNP) | VAF 12/112 reads (11%) | catalogued as COSV63544133; called by muse, mutect2
- PCDHA7 | c.1164C>A p.S388= | Silent (SNP) | VAF 31/221 reads (14%) | catalogued as COSV65346015; called by muse, mutect2, varscan2
- PCDHB9 | c.1995C>T p.G665= | Silent (SNP) | VAF 10/201 reads (5%) | catalogued as COSV53375750; called by muse, mutect2
- PCDHGA6 | c.1857G>A p.V619= | Silent (SNP) | VAF 6/82 reads (7%) | catalogued as COSV53992146; called by muse, mutect2
- PCK1 | c.339C>A p.L113= | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as COSV60129884; called by muse, mutect2, varscan2
- PDE4B | c.201G>A p.E67= | Silent (SNP) | VAF 12/164 reads (7%) | catalogued as COSV58487122; called by muse, mutect2
- PDZD7 | c.150G>A p.L50= | Silent (SNP) | VAF 27/155 reads (17%) | catalogued as rs1247745897, COSV56520608; called by muse, mutect2, varscan2
- PIWIL4 | c.324G>T p.L108= | Silent (SNP) | VAF 8/95 reads (8%) | catalogued as COSV54411043, COSV54411498; called by muse, mutect2
- PKD1 | c.10065G>T p.P3355= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as COSV51921223; called by muse, mutect2, varscan2
- PLEKHM1 | c.2931C>G p.L977= | Silent (SNP) | VAF 10/127 reads (8%) | catalogued as COSV69599237; called by muse, mutect2
- PLIN4 | c.228G>T p.G76= (on ENST00000301286; = p.G91= on NM_001367868.2) | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as COSV100012836; called by muse, mutect2, varscan2
- PLXNB3 | c.5088G>T p.L1696= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV100737177; called by muse, mutect2
- POLR2G | c.99G>A p.E33= | Silent (SNP) | VAF 19/167 reads (11%) | catalogued as rs1258028678, COSV57135452; called by muse, mutect2, varscan2
- POM121L12 | c.213G>T p.P71= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as rs369662403, COSV68692841; called by muse, mutect2, varscan2
- PPM1J | c.1092C>G p.V364= | Silent (SNP) | VAF 138/625 reads (22%) | catalogued as COSV53518665; called by muse, mutect2, varscan2
- PRG3 | c.498C>A p.L166= | Silent (SNP) | VAF 28/440 reads (6%) | catalogued as COSV54664214; called by muse, mutect2
- PRKD1 | c.1296C>T p.Y432= | Silent (SNP) | VAF 30/324 reads (9%) | catalogued as COSV59577859; called by muse, mutect2
- PRLHR | c.1110C>A p.I370= | Silent (SNP) | VAF 11/72 reads (15%) | catalogued as COSV53304555; called by muse, mutect2, varscan2
- PTCD2 | c.1062C>T p.L354= | Silent (SNP) | VAF 9/87 reads (10%) | catalogued as COSV57338564; called by muse, mutect2, varscan2
- RAD54B | c.1974A>T p.R658= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV60253244; called by muse, mutect2, varscan2
- RANBP3L | c.927C>T p.F309= | Silent (SNP) | VAF 12/148 reads (8%) | catalogued as COSV56956881, COSV56958708; called by muse, mutect2
- RBPJL | c.120C>G p.G40= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as COSV59215029; called by muse, mutect2, varscan2
- RNASE12 | c.372C>T p.S124= | Silent (SNP) | VAF 8/94 reads (9%) | catalogued as rs1425055042, COSV60087598, COSV60087745; called by muse, mutect2
- RNF17 | c.486C>T p.F162= | Silent (SNP) | VAF 23/106 reads (22%) | catalogued as rs777537434, COSV55036755, COSV55049077; called by muse, mutect2, varscan2
- RO60 | c.1023G>A p.L341= | Silent (SNP) | VAF 5/52 reads (10%) | catalogued as COSV66474410; called by muse, mutect2
- ROBO2 | c.2994C>A p.A998= | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as rs1383654175, COSV59926237; called by muse, mutect2, varscan2
- RUFY2 | c.492G>A p.R164= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as COSV61191825; called by muse, mutect2
- SCRN2 | c.1104G>A p.L368= | Silent (SNP) | VAF 12/141 reads (9%) | catalogued as rs751227060, COSV51636765, COSV51636856; called by muse, mutect2
- SEC14L3 | c.1116C>A p.V372= | Silent (SNP) | VAF 20/140 reads (14%) | catalogued as COSV53180668; called by muse, mutect2, varscan2
- SEMA5B | c.2233C>A p.R745= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs1356495559, COSV52111111, COSV99531003; called by muse, mutect2
- SLC22A12 | c.1167C>T p.D389= | Silent (SNP) | VAF 21/145 reads (14%) | catalogued as rs1265714483, COSV60573198; called by muse, mutect2, varscan2
- SLC22A7 | c.807C>A p.A269= (on ENST00000372585 / NM_153320.2; = p.A267= on NM_006672.3) | Silent (SNP) | VAF 18/158 reads (11%) | catalogued as rs954963680, COSV65355233; called by muse, mutect2, varscan2
- SLC38A10 | c.1086G>T p.P362= | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as rs540178428, COSV99917249; called by muse, mutect2, varscan2
- SLC52A2 | c.600G>A p.L200= | Silent (SNP) | VAF 14/147 reads (10%) | catalogued as COSV57352735; called by muse, mutect2
- SLC6A7 | c.294C>A p.G98= | Silent (SNP) | VAF 25/228 reads (11%) | catalogued as COSV57939609, COSV57940597; called by muse, mutect2, varscan2
- SLC9A4 | c.606G>C p.L202= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as COSV54836889; called by muse, mutect2, varscan2
- SLIT2 | c.3138C>A p.P1046= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as COSV56584399; called by muse, mutect2
- SLITRK3 | c.2562G>T p.G854= | Silent (SNP) | VAF 30/236 reads (13%) | catalogued as COSV53850169; called by muse, mutect2, varscan2
- SMG1 | c.8205G>T p.V2735= | Silent (SNP) | VAF 35/277 reads (13%) | catalogued as COSV67173519; called by muse, mutect2, varscan2
- SOAT1 | c.1524C>T p.F508= | Silent (SNP) | VAF 16/168 reads (10%) | catalogued as COSV62655817; called by muse, mutect2
- SOX7 | c.732G>T p.P244= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as COSV100449221, COSV58731290; called by muse, mutect2, varscan2
- SSTR1 | c.72C>A p.G24= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV57456916, COSV99943232; called by muse, mutect2, varscan2
- STKLD1 | c.1521C>A p.I507= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV100905711; called by muse, mutect2
- SUGP2 | c.240G>C p.L80= | Silent (SNP) | VAF 12/78 reads (15%) | catalogued as COSV58262182; called by muse, varscan2
- TBX2 | c.960A>T p.S320= | Silent (SNP) | VAF 3/11 reads (27%) | catalogued as COSV53600158; called by muse, mutect2
- TDRD7 | c.426G>C p.P142= | Silent (SNP) | VAF 22/126 reads (17%) | catalogued as COSV62430452; called by muse, mutect2, varscan2
- TMCC2 | c.1446C>T p.A482= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as COSV58005255; called by muse, mutect2, varscan2
- TMEM236 | c.363C>A p.V121= | Silent (SNP) | VAF 113/740 reads (15%) | called by muse, mutect2, varscan2
- TNFRSF9 | c.624C>T p.L208= | Silent (SNP) | VAF 4/41 reads (10%) | catalogued as COSV66349370, COSV66349421; called by muse, mutect2
- TRAFD1 | c.267C>T p.V89= | Silent (SNP) | VAF 12/158 reads (8%) | catalogued as COSV57505391; called by muse, mutect2
- TTN | c.28662G>A p.E9554= (on ENST00000591111; = p.E8627= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/151 reads (12%) | catalogued as COSV60207454; called by muse, mutect2, varscan2
- TXNDC16 | c.2088G>A p.L696= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as rs746484184, COSV55985980, COSV55987290; called by muse, mutect2, varscan2
- UIMC1 | c.1620G>A p.E540= | Silent (SNP) | VAF 19/112 reads (17%) | catalogued as rs149513554; called by muse, mutect2, varscan2
- USF3 | c.981C>T p.F327= | Silent (SNP) | VAF 12/102 reads (12%) | catalogued as COSV57075382, COSV57076395; called by muse, mutect2, varscan2
- USH2A | c.7095C>T p.F2365= | Silent (SNP) | VAF 16/192 reads (8%) | catalogued as COSV56403538; called by muse, mutect2
- USP20 | c.1914G>A p.T638= | Silent (SNP) | VAF 32/177 reads (18%) | catalogued as rs776188342, COSV59616527; called by muse, mutect2, varscan2
- WASF3 | c.1422G>T p.V474= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as COSV58968930; called by muse, mutect2, varscan2
- ZBP1 | c.822C>A p.L274= | Silent (SNP) | VAF 5/50 reads (10%) | catalogued as COSV100473123; called by muse, mutect2
- ZC3H12A | c.1443C>T p.T481= | Silent (SNP) | VAF 12/138 reads (9%) | catalogued as rs151076639; called by muse, mutect2
- ZG16B | c.135C>T p.L45= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as COSV66526122; called by muse, mutect2
- ZNF2 | c.93G>T p.L31= | Silent (SNP) | VAF 28/163 reads (17%) | catalogued as COSV54637731; called by muse, mutect2, varscan2
- ZNF24 | c.702C>T p.F234= | Silent (SNP) | VAF 13/91 reads (14%) | catalogued as COSV54349011; called by muse, mutect2, varscan2
- ZNF532 | c.3192C>T p.F1064= | Silent (SNP) | VAF 14/236 reads (6%) | catalogued as rs1477924079, COSV60174563; called by muse, mutect2
- ZNF705A | c.177G>A p.L59= | Silent (SNP) | VAF 13/105 reads (12%) | catalogued as COSV100828276; called by mutect2, varscan2
- AL353804.6 | chrX:73826220 C>A | 3'Flank (SNP) | VAF 9/67 reads (13%) | called by muse, varscan2
- AP000769.3 | chr11:65505877 G>C | 5'Flank (SNP) | VAF 7/107 reads (7%) | called by muse, mutect2
- AP003393.1 | n.514+773G>T | Intron (SNP) | VAF 6/40 reads (15%) | catalogued as rs751567128, COSV58226264, COSV58227475; called by muse, varscan2
- CPED1 | c.2311-4578G>T | Intron (SNP) | VAF 4/28 reads (14%) | catalogued as COSV100120241; called by mutect2, varscan2
- DEFB119 | c.61+1300A>T | Intron (SNP) | VAF 18/161 reads (11%) | catalogued as COSV100190594; called by muse, mutect2, varscan2
- DNAH14 | c.749-4200G>T | Intron (SNP) | VAF 10/145 reads (7%) | catalogued as COSV64781497; called by muse, mutect2
- HMGB1P1 | n.198G>A | RNA (SNP) | VAF 14/162 reads (9%) | catalogued as rs373550519; called by muse, mutect2
- MIR892A | n.47C>A | RNA (SNP) | VAF 56/200 reads (28%) | catalogued as rs1297364622; called by muse, mutect2, varscan2
- PCDHGA6 | c.2424+23G>T | Intron (SNP) | VAF 6/32 reads (19%) | catalogued as rs200613052, COSV53935057; called by muse, mutect2
- PCDHGA6 | c.2424+24G>T | Intron (SNP) | VAF 6/32 reads (19%) | catalogued as rs1240526589; called by muse, mutect2
- PTX4 | c.141+349G>T | Intron (SNP) | VAF 15/103 reads (15%) | catalogued as COSV51979924; called by muse, mutect2, varscan2
- SLC17A2 | c.*117G>T | 3'UTR (SNP) | VAF 15/161 reads (9%) | catalogued as COSV55353880; called by muse, mutect2
- UBTFL2 | n.290G>T | RNA (SNP) | VAF 7/32 reads (22%) | called by muse, mutect2, varscan2
